Somatic mutation profile of tumor specimen TCGA-D1-A0ZU-01A (aliquot TCGA-D1-A0ZU-01A-11D-A10M-09) from TCGA case TCGA-D1-A0ZU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 34.1 years (12,458 days).
Specimen TCGA-D1-A0ZU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b458fd2-a41e-4427-af29-1aedb371fc91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZU-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZU-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8572c58-7d94-44f1-957c-85ce9b2d0923

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 17, Silent 12, Nonsense Mutation 4, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- CCND1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1008C>G p.Y336* | Nonsense Mutation (SNP) | VAF 21/25 reads (84%) | hotspot (GDC flag); catalogued as rs786201816, COSV64292408, COSV64294380, COSV64309461; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP31 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51795895; called by muse, mutect2, varscan2
- FLT1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as rs763344343, COSV56733747, COSV56747702; called by muse, varscan2
- GDE1 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54900792, COSV54906584; called by muse, mutect2, varscan2
- GNE | c.1651T>G p.C551G (on ENST00000396594 / NM_001128227.3; = p.C520G on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs912831036, COSV64952441; called by muse, mutect2, varscan2
- GPR179 | c.3809C>T p.T1270M (on ENST00000621958; = p.T1269M on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754266923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLC3 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs745583423, COSV67269134; called by muse, mutect2, varscan2
- KRTAP19-8 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV66998476; called by muse, mutect2, varscan2
- NIPBL | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80358380, CM042516, COSV56942266, COSV56950421; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDHGA3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs772663259, COSV53983590; called by muse, mutect2, varscan2
- PKHD1L1 | c.6067G>A p.G2023R | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747646955, COSV65747248; called by muse, mutect2, varscan2
- PLIN3 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370671939, COSV55735976; called by muse, mutect2, varscan2
- PPP5C | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs150667064, COSV50141193; called by muse, mutect2, varscan2
- SLC22A13 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61291529; called by muse, mutect2
- SLC34A2 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as COSV65942235; called by muse, mutect2, varscan2
- SMTN | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60780222; called by muse, mutect2, varscan2
- AP1G2 | c.530_533del p.L177Hfs*21 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | called by mutect2, pindel, varscan2
- CRELD2 | c.905_906del p.V302Efs*19 | Frame Shift Del (DEL) | VAF 63/284 reads (22%) | called by pindel, varscan2
- KDM6A | c.3160dup p.R1054Kfs*5 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- MED12 | c.222_248del p.S75_C83del | In Frame Del (DEL) | VAF 16/105 reads (15%) | called by mutect2, pindel
- NOG | c.415_423dup p.K139_L141dup | In Frame Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- BRD8 | c.2904T>C p.S968= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV54729056; called by muse, mutect2
- KAT14 | c.309G>A p.R103= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs200083646, COSV66608419; called by muse, mutect2, varscan2
- KDM4C | c.2661G>A p.T887= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1266512283, COSV67188736; called by muse, mutect2, varscan2
- KRT23 | c.1263C>T p.H421= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs775010306, COSV52928408; called by muse, mutect2, varscan2
- KRT85 | c.900C>T p.D300= | Silent (SNP) | VAF 75/181 reads (41%) | catalogued as rs372918365; called by muse, mutect2, varscan2
- MCF2L2 | c.519C>T p.H173= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs148174419; called by muse, mutect2, varscan2
- NLRP5 | c.795G>A p.T265= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as rs779091654, COSV66765953; called by muse, mutect2, varscan2
- PCLO | c.5082C>T p.D1694= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs367988765, COSV100436349; called by muse, mutect2, varscan2
- PIK3R5 | c.2571G>T p.P857= | Silent (SNP) | VAF 60/170 reads (35%) | catalogued as COSV52655979; called by muse, mutect2, varscan2
- TATDN1 | c.414G>A p.L138= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV52680752; called by muse, mutect2, varscan2
- TENM1 | c.6105G>T p.V2035= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100949688; called by muse, mutect2
- ZBTB16 | c.1974G>A p.P658= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs757004570, COSV60090602; called by muse, mutect2, varscan2
